Somatic mutation profile of tumor specimen ALCH-B0D5-TTP1-A (aliquot ALCH-B0D5-TTP1-A-1-0-D-A694-36) from ALCHEMIST case ALCH-B0D5, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,781 days).
Specimen ALCH-B0D5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5bd5002c-c3b0-4db7-ad8a-84d5e4e63274.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0D5-NB1-A (Blood Derived Normal), aliquot ALCH-B0D5-NB1-A-1-0-D-A695-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa5c576d-4115-4652-8c65-8706371cc66a

The open-access MAF lists 216 somatic variants for this specimen: 149 protein-altering or splice-affecting, 44 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 44, Intron 9, Nonsense Mutation 9, RNA 5, 5'UTR 4, Splice Region 3, Splice Site 2, Frame Shift Del 2, 5'Flank 2, 3'UTR 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 14/119 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKRD13C | c.1477G>T p.G493C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52035317; called by muse, varscan2
- AR | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 26/129 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.015); catalogued as COSV65955940; called by muse, mutect2, varscan2
- BPNT1 | c.602A>T p.K201M | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.279); catalogued as COSV100435571, COSV59040363; called by muse, mutect2
- CABIN1 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as rs567017068; called by muse, mutect2
- CADM3 | c.218G>A p.G73E (on ENST00000368125 / NM_001127173.3; = p.G107E on NM_021189.5) | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV63684218; called by muse, mutect2
- CAMTA1 | c.1502G>T p.G501V | Missense Mutation (SNP) | VAF 30/392 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.518); catalogued as COSV57891255; called by muse, mutect2
- CGB5 | c.257C>A p.S86Y | Missense Mutation (SNP) | VAF 23/684 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100031969; called by muse, mutect2
- CHST6 | c.1013C>A p.P338H | Missense Mutation (SNP) | VAF 83/836 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100178233; called by muse, mutect2
- COL1A2 | c.3832T>A p.Y1278N | Missense Mutation (SNP) | VAF 20/177 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51967054; called by muse, mutect2, varscan2
- EYA4 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1215782368, COSV62054648; ClinVar: uncertain significance; called by muse, mutect2
- FABP5 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs1393545719, COSV51917500; called by muse, mutect2, varscan2
- FOXD3 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs757568482; called by muse, mutect2, varscan2
- GNL1 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 46/468 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64835436; called by muse, mutect2, varscan2
- GRM1 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 34/420 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.197); catalogued as rs753190249, COSV51129492; called by muse, mutect2
- GRN | c.1404G>T p.Q468H | Missense Mutation (SNP) | VAF 32/426 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.909); catalogued as COSV50006411; called by muse, mutect2
- HTR5A | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 14/282 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); catalogued as COSV55280587, COSV99840025; called by muse, mutect2
- IGFN1 | c.2678C>A p.P893Q (on ENST00000295591 / NM_001367841.1; = p.P3350Q on NM_001164586.2) | Missense Mutation (SNP) | VAF 36/414 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.498); catalogued as rs752567503, COSV99813233; called by muse, mutect2
- IGSF11 | c.1099G>T p.G367C (on ENST00000393775 / NM_001015887.3; = p.G366C on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as rs1267616069; called by muse, mutect2, varscan2
- IGSF11 | c.668C>A p.T223N (on ENST00000393775 / NM_001015887.3; = p.T222N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV61165690; called by muse, mutect2, varscan2
- IGSF21 | c.844G>C p.E282Q | Missense Mutation (SNP) | VAF 38/589 reads (6%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.744); catalogued as COSV99243806; called by muse, mutect2
- KCTD19 | c.1114G>T p.E372* | Nonsense Mutation (SNP) | VAF 11/106 reads (10%) | catalogued as COSV58572199; called by muse, mutect2, varscan2
- LINC00482 | n.430A>G | Splice Region (SNP) | VAF 39/289 reads (13%) | catalogued as rs534982564; called by muse, mutect2, varscan2
- MAGEB6 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.035); catalogued as COSV66872494; called by muse, mutect2
- MC3R | c.331C>A p.Q111K | Missense Mutation (SNP) | VAF 78/562 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.037); catalogued as COSV99710381; called by muse, mutect2, varscan2
- MT2A | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/330 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs368767847; called by muse, mutect2
- MUC16 | c.33947C>T p.P11316L | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.262); catalogued as COSV67450085; called by muse, mutect2, varscan2
- MYL2 | c.349G>T p.D117Y | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV57406913; called by muse, mutect2, varscan2
- NCKAP5L | c.3916G>T p.A1306S | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.305); catalogued as rs1207492626; called by muse, mutect2
- NOX1 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as COSV54193235; called by muse, mutect2, varscan2
- OR1L3 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100506299; called by muse, mutect2, varscan2
- OR2C3 | c.261G>T p.W87C | Missense Mutation (SNP) | VAF 23/326 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100825566, COSV63576627; called by muse, mutect2
- OR6Q1 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV56932607; called by muse, mutect2
- PAPPA | c.3277C>A p.P1093T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755070797; called by mutect2, varscan2
- PIK3C2G | c.2564C>T p.A855V (on ENST00000676171; = p.A814V on NM_004570.5) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV56831459; called by muse, varscan2
- PITPNM3 | c.256A>T p.I86F | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs753567350; called by muse, mutect2
- PPP3CA | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 12/140 reads (9%) | catalogued as COSV59921283; called by muse, mutect2
- PTK2 | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1224702542, COSV61787366; called by muse, mutect2
- PTPRB | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.207); catalogued as COSV54236360; called by muse, mutect2
- PYGO1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs564470411, COSV57347357; called by muse, mutect2
- RASGEF1C | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 19/203 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1361771640; called by muse, mutect2
- SHC4 | c.303G>T p.L101F | Missense Mutation (SNP) | VAF 36/313 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as rs1350787741; called by muse, mutect2, varscan2
- SNX25 | c.488G>A p.R163K | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV53017911; called by muse, mutect2
- SPTBN4 | c.4512G>T p.L1504F | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1209187367, COSV100150536; called by muse, mutect2, varscan2
- SRRM2 | c.8224C>T p.R2742W | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs746760304, COSV51939998; called by muse, mutect2
- SYT3 | c.1540G>A p.V514M | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs377637160; called by muse, mutect2
- TBXAS1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 35/320 reads (11%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1229224144, COSV99694910; called by muse, mutect2, varscan2
- TECRL | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV101169152; called by muse, mutect2
- THEG | c.818A>T p.K273M | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100700602; called by muse, mutect2
- TMEM150B | c.6G>A p.W2* | Nonsense Mutation (SNP) | VAF 14/218 reads (6%) | catalogued as COSV58593783; called by muse, mutect2
- TP53I13 | c.916C>A p.R306S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56402258; called by muse, mutect2, varscan2
- TPSAB1 | c.815C>A p.P272H | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs1279735089; called by muse, mutect2, varscan2
- TRAPPC12 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs1381006702; called by muse, mutect2
- TRAV1-2 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as rs569901358; called by muse, mutect2
- TRHDE | c.1588-1G>T p.X530_splice | Splice Site (SNP) | VAF 8/58 reads (14%) | catalogued as COSV99670368; called by muse, varscan2
- ZBTB18 | c.1131G>T p.K377N | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV62397405; called by muse, mutect2
- ACAN | c.6170G>T p.R2057M | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.965); called by muse, mutect2
- ADGRA3 | c.3154G>T p.D1052Y | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AGGF1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- AMIGO2 | c.1505G>C p.G502A | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- ATP13A2 | c.2012C>G p.T671S | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2
- BAZ2A | c.2887T>A p.F963I | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- BCR | c.2305G>T p.E769* | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | called by muse, mutect2
- C19orf84 | c.502G>C p.G168R | Missense Mutation (SNP) | VAF 42/464 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2
- C21orf62 | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.343); called by muse, mutect2
- C6orf118 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 14/222 reads (6%) | called by muse, mutect2
- CACNA1E | c.4378A>G p.M1460V | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); called by muse, mutect2
- CAMKMT | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC178 | c.2525A>C p.E842A (on ENST00000383096 / NM_001105528.3; = p.E804A on NM_198995.3) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CCT8L2 | c.1430T>A p.L477Q | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CD48 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CRYBB1 | c.631G>T p.G211C | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); called by muse, mutect2
- DENND4B | c.3505G>A p.D1169N | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ELFN1 | c.752C>A p.T251N | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- ELFN1 | c.1166G>C p.R389P | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- EMILIN3 | c.221G>C p.G74A | Missense Mutation (SNP) | VAF 19/336 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ENPP2 | c.1948A>T p.T650S (on ENST00000075322 / NM_001040092.3; = p.T702S on NM_006209.5) | Missense Mutation (SNP) | VAF 13/194 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- EPHA4 | c.656C>A p.T219K | Missense Mutation (SNP) | VAF 9/214 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- FKTN | c.1019T>G p.L340R | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FPGT-TNNI3K | c.1586A>C p.E529A | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2
- GABRG2 | c.52G>T p.V18L | Missense Mutation (SNP) | VAF 29/281 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNL3L | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GOLGA3 | c.1336A>T p.S446C | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- GPR179 | c.4723C>T p.P1575S (on ENST00000621958; = p.P1574S on NM_001004334.4) | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GPR32 | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- GPR89B | c.910-1G>T p.X304_splice | Splice Site (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- GTF2H1 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.164); called by muse, varscan2
- GZMA | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- HCN1 | c.2270C>A p.T757K | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.018); called by muse, mutect2
- HMG20B | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2
- HMX2 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 22/205 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.676); called by muse, varscan2
- HOXC11 | c.53G>T p.R18M | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- ICA1 | c.1040A>T p.D347V | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.636); called by muse, varscan2
- IFI44L | c.950A>T p.H317L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGSF21 | c.1352G>T p.G451V | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.755); called by muse, mutect2
- KCNMB4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 15/226 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.202); called by muse, mutect2
- KCTD11 | c.295G>A p.E99K (on ENST00000333751 / NM_001363642.1; = p.E60K on NM_001002914.2) | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM4B | c.592A>T p.I198F | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- KLF14 | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.742); called by muse, mutect2
- LACTB | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- LHX5 | c.278T>G p.M93R | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- LRP1B | c.8368G>T p.G2790* | Nonsense Mutation (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- MAP3K3 | c.1526G>T p.G509V | Missense Mutation (SNP) | VAF 41/367 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAPT | c.1633A>G p.T545A (on ENST00000262410 / NM_001377265.1; = p.T153A on NM_005910.5) | Missense Mutation (SNP) | VAF 29/616 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.635); called by muse, mutect2
- MUC16 | c.18737C>T p.S6246F | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.8138C>A p.S2713* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- MUC17 | c.9440C>A p.T3147K | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- MYH8 | c.2127G>C p.R709S | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MYT1L | c.2745_2746delinsA p.G916Afs*22 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | called by pindel, varscan2*
- NDUFB1 | c.155G>T p.S52I | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2
- NEU2 | c.264C>G p.C88W | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOS2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- OR10P1 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); called by muse, mutect2
- OR2L2 | c.496C>A p.P166T | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- OR8K3 | c.713C>A p.S238Y | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PDGFRB | c.1581C>A p.S527= | Splice Region (SNP) | VAF 26/248 reads (10%) | called by muse, mutect2
- PDZRN3 | c.909G>T p.R303S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PLAC8L1 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRAMEF1 | c.1345A>T p.R449W | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2
- PRKCG | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRR12 | c.329C>T p.S110F (on ENST00000615927; = p.S931F on NM_020719.3) | Missense Mutation (SNP) | VAF 41/409 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PSMB5 | c.594G>T p.M198I | Missense Mutation (SNP) | VAF 25/265 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.007); called by muse, mutect2
- RAG2 | c.1290G>T p.W430C | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RBM45 | c.949A>G p.I317V (on ENST00000616198 / NM_001365579.1; = p.I315V on NM_152945.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- RGPD3 | c.1760G>T p.G587V | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- ROBO4 | c.1663C>A p.P555T | Missense Mutation (SNP) | VAF 39/331 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RYR2 | c.13992C>A p.D4664E | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SERPINB12 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SLC17A1 | c.36T>A p.V12= | Splice Region (SNP) | VAF 6/36 reads (17%) | called by mutect2, varscan2
- SLC6A4 | c.720C>A p.H240Q | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2
- SLIT1 | c.3494T>G p.L1165W | Missense Mutation (SNP) | VAF 43/442 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPATA16 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SPTAN1 | c.2601G>T p.E867D | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.115); called by muse, varscan2
- STEAP4 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- STIM1 | c.112del p.A38Pfs*37 | Frame Shift Del (DEL) | VAF 18/135 reads (13%) | called by mutect2, pindel, varscan2
- TIGIT | c.688A>T p.S230C | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- TNRC18 | c.6694G>T p.A2232S | Missense Mutation (SNP) | VAF 12/254 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.183); called by muse, mutect2
- TPSAB1 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- UGGT2 | c.2571G>C p.Q857H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, mutect2
- UMODL1 | c.344C>A p.T115K | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); called by mutect2, varscan2
- USH1G | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 80/1008 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- VCAN | c.2573C>T p.P858L | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- VWF | c.4327G>T p.V1443L | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- WDR86 | c.536A>G p.Q179R | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.348); called by muse, mutect2
- WNT8B | c.275G>A p.S92N | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, varscan2
- XIRP2 | c.8973C>A p.H2991Q (on ENST00000628543; = p.H3166Q on NM_152381.6) | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ZC3H14 | c.1573G>T p.V525F | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF135 | c.1778T>A p.L593H (on ENST00000313434 / NM_001289401.2; = p.L605H on NM_003436.4) | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF536 | c.1698C>A p.Y566* | Nonsense Mutation (SNP) | VAF 31/389 reads (8%) | called by muse, mutect2
- AGAP3 | c.2514G>A p.L838= (on ENST00000622464; = p.L874= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- ALG8 | c.1299C>T p.L433= | Silent (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- BEND2 | c.1557G>T p.L519= | Silent (SNP) | VAF 13/101 reads (13%) | called by muse, mutect2, varscan2
- C9orf50 | c.765C>T p.H255= | Silent (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- CAMTA1 | c.1242C>A p.P414= | Silent (SNP) | VAF 24/266 reads (9%) | called by muse, mutect2
- CDH3 | c.2049C>T p.I683= | Silent (SNP) | VAF 34/402 reads (8%) | called by muse, mutect2
- CDH7 | c.396C>A p.P132= | Silent (SNP) | VAF 35/297 reads (12%) | called by muse, mutect2, varscan2
- CEP192 | c.6807C>T p.S2269= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- CFH | c.3600G>T p.V1200= | Silent (SNP) | VAF 23/278 reads (8%) | called by muse, mutect2
- CSGALNACT2 | c.987T>A p.S329= | Silent (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- DENND6B | c.1719C>T p.S573= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- DHRS13 | c.273C>T p.F91= | Silent (SNP) | VAF 20/224 reads (9%) | catalogued as rs763368832, COSV60454516; called by muse, mutect2
- DLGAP1 | c.2028C>A p.S676= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV59780862, COSV59831544; called by muse, mutect2
- FMN2 | c.861C>A p.P287= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1330745634; called by muse, mutect2, varscan2
- HTR5A | c.273G>A p.A91= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as rs780287431, COSV55281757; called by muse, mutect2, varscan2
- ITGAD | c.2958C>T p.A986= | Silent (SNP) | VAF 15/112 reads (13%) | catalogued as COSV54932707, COSV54932740; called by muse, mutect2, varscan2
- KCNAB3 | c.819C>G p.L273= | Silent (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- LRFN5 | c.1224C>T p.S408= | Silent (SNP) | VAF 10/74 reads (14%) | called by muse, varscan2
- LRIG2 | c.3015C>T p.G1005= | Silent (SNP) | VAF 17/172 reads (10%) | catalogued as rs769312738; called by muse, varscan2
- MSRB3 | c.36G>T p.S12= | Silent (SNP) | VAF 41/263 reads (16%) | called by muse, mutect2, varscan2
- MYH13 | c.2895G>A p.L965= | Silent (SNP) | VAF 9/79 reads (11%) | called by muse, mutect2, varscan2
- NBPF10 | c.1233G>A p.Q411= | Silent (SNP) | VAF 25/223 reads (11%) | called by muse, mutect2, varscan2
- NCAPD3 | c.2904C>G p.L968= | Silent (SNP) | VAF 19/314 reads (6%) | called by muse, mutect2
- NMUR2 | c.270T>C p.S90= | Silent (SNP) | VAF 24/241 reads (10%) | called by muse, mutect2, varscan2
- NRM | c.453C>T p.L151= | Silent (SNP) | VAF 19/231 reads (8%) | called by muse, mutect2
- NTF3 | c.729C>T p.D243= | Silent (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- OR2F2 | c.951T>A p.T317= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- OR51D1 | c.171C>G p.T57= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV62914402; called by muse, mutect2
- OTOGL | c.4827A>T p.I1609= (on ENST00000547103; = p.I1600= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2, varscan2
- OTOP3 | c.1260G>T p.V420= | Silent (SNP) | VAF 28/236 reads (12%) | called by muse, mutect2, varscan2
- PCDHGB1 | c.2355A>C p.V785= | Silent (SNP) | VAF 27/252 reads (11%) | called by muse, mutect2, varscan2
- PHF1 | c.66T>G p.A22= | Silent (SNP) | VAF 25/354 reads (7%) | called by muse, mutect2
- PTPRT | c.3762C>A p.P1254= | Silent (SNP) | VAF 26/480 reads (5%) | called by muse, mutect2
- SERPINB13 | c.192G>A p.K64= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as COSV54031036; called by muse, mutect2, varscan2
- SIGLEC11 | c.1521C>A p.P507= | Silent (SNP) | VAF 17/361 reads (5%) | called by muse, mutect2
- SRP54 | c.309G>T p.V103= | Silent (SNP) | VAF 14/150 reads (9%) | called by muse, mutect2, varscan2
- TBX2 | c.1980C>T p.P660= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs371416364; called by muse, mutect2, varscan2
- TMCC3 | c.192C>G p.V64= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2, varscan2
- USH2A | c.4119C>A p.L1373= | Silent (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- USP6NL | c.2094A>T p.I698= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- ZIC2 | c.1086G>T p.P362= | Silent (SNP) | VAF 46/442 reads (10%) | called by muse, mutect2, varscan2
- ZNF577 | c.54A>T p.S18= | Silent (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2
- ZNF670 | c.306A>G p.P102= | Silent (SNP) | VAF 23/158 reads (15%) | catalogued as rs763924657; called by muse, mutect2, varscan2
- ZNF808 | c.387G>T p.T129= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV63121471; called by mutect2, varscan2
- AC004890.2 | n.2179C>T | RNA (SNP) | VAF 22/282 reads (8%) | catalogued as rs1358854244; called by muse, mutect2
- AC092718.9 | chr16:81157065 G>A | 3'Flank (SNP) | VAF 15/201 reads (7%) | called by muse, mutect2
- AC244517.10 | c.36-9747G>T | Intron (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- ADAM33 | c.333+63C>T | Intron (SNP) | VAF 45/191 reads (24%) | called by muse, mutect2, varscan2
- AL121899.2 | c.*362T>A | 3'UTR (SNP) | VAF 24/221 reads (11%) | catalogued as rs45572444; called by muse, mutect2, varscan2
- ANKMY1 | c.-88G>T | 5'UTR (SNP) | VAF 17/162 reads (10%) | called by muse, mutect2, varscan2
- CACNB4 | c.699+25C>T | Intron (SNP) | VAF 27/182 reads (15%) | called by muse, mutect2, varscan2
- CD55 | c.1081+1172T>C | Intron (SNP) | VAF 8/89 reads (9%) | catalogued as rs1260729418; called by muse, mutect2
- COL18A1-AS1 | n.1655A>C | RNA (SNP) | VAF 32/354 reads (9%) | called by muse, mutect2
- CRACR2B | c.278-16C>G | Intron (SNP) | VAF 10/75 reads (13%) | catalogued as rs761922699, COSV58989698; called by muse, mutect2, varscan2
- HCN1 | c.-3G>A | 5'UTR (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- KLF6 | c.677-13G>T | Intron (SNP) | VAF 24/381 reads (6%) | called by muse, mutect2
- MIR514A1 | n.69C>A | RNA (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- NAA40 | chr11:63939000 C>T | 5'Flank (SNP) | VAF 10/110 reads (9%) | called by muse, mutect2
- NDRG4 | c.-42G>C | 5'UTR (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- PSG9 | c.-6G>A | 5'UTR (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- RRN3P1 | chr16:21811781 C>A | 5'Flank (SNP) | VAF 8/99 reads (8%) | called by muse, mutect2, varscan2
- SERPINA13P | n.646G>T | RNA (SNP) | VAF 12/117 reads (10%) | called by muse, mutect2
- SLC25A12 | c.326-1322A>G | Intron (SNP) | VAF 17/102 reads (17%) | catalogued as rs1324308500; called by muse, mutect2, varscan2
- SZRD1 | c.52-3817T>C | Intron (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- TBL3 | c.*720C>T | 3'UTR (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- TERB2 | c.64+38G>A | Intron (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- ZNF767P | n.631G>T | RNA (SNP) | VAF 15/199 reads (8%) | called by muse, mutect2
